Surgical pathology report (de-identified scan), TCGA case TCGA-DR-A0ZM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Hawaii, specimen TCGA-DR-A0ZM-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Patient Name:
Med Rec No:
DOB:
Gender:
Physician(s):
cc:

Client:
Location:
Pt. Phone no

Accession #:
Taken:
Received:
Reported:

History/Clinical Dx: Invasive cervical cancer

Postoperative Dx: Pending pathology examination

Specimen(s) Received:

- A: Left pelvic lymph node
- B: Left common lymph node
- C: Right pelvic lymph node
- D: Posterior vaginal cuff biopsy
- E: Uterus, cervix, tubes and ovaries

1CD-0-3
carcinoma, squamous cell 807013
Site: cervix, NOS C53.9
hw
8/31/11

DIAGNOSIS:

- A. Left pelvic lymph nodes: METASTASIS TO TWO OF TWENTY-SEVEN LYMPH NODES (2/27)
- B. Left common lymph nodes: Five lymph nodes negative for metastasis (0/5)
- C. Right pelvic lymph nodes: METASTASIS TO TWO OF TWENTY-SIX LYMPH NODES (2/26)
- D. Posterior vaginal cuff biopsy: Vaginal mucosa with no evidence of tumor or dysplasia
- E. Uterus, cervix, tubes and ovaries: CERVICAL SQUAMOUS CELL CARCINOMA

Tumor Information:

Type of specimen:	Radical hysterectomy
Tumor location:	Anterior and posterior cervix
Tumor size:	7.5 cm
Histologic type:	Squamous
Histologic grade:	Moderately differentiated
Depth of invasion:	1.5 cm (completely through cervical wall)
Lower third of vagina involvement:	Absent
Pelvic wall extension:	Absent
Parametrial invasion:	Present
Bladder/rectal mucosal extension:	Absent
Lymphovascular invasion:	Present, extensive
Resection margins:	Paracervical margin clear by less than 0.1 cm
Lymph node involvement:	Present, see above
Other findings:	Extension and extensive involvement of the myometrium

Regulatory Statement:

The following statement may be applicable to some of the information used in developing this report: This report was developed and its performance characteristics were determined by the U.S. Food and Drug Administration. The FDA has determined that this information is essential for the safe and effective use of this device. This information is not intended to be used for any other purpose. It is not intended to be used for any other purpose. It is not intended to be used for any other purpose.

[page 2 of 3]
Surgical Pathology Report

Staging information:

T2b, N1 (Stage IIIB)

Gross Description

- A. Received in formalin labeled "1 lt pelvic lymph nodes" are multiple fragments of soft tan to yellow tissue, 28.0 gms, aggregating up to 7.5 x 5.0 x 3.4 cm. There are 16 lymph nodes, identified, largest up to 3.7 x 1.5 x 1.4 cm (inked blue). Submitted in toto in six cassettes as follows: 1 lymph node in A1 (largest-blue), 5 lymph nodes in A2, 5 lymph nodes in A3, 5 lymph nodes in A4, rest of specimen in A5 and A6.
- B. Received in formalin labeled "2 lt common nodes" are two pieces of soft tan to yellow tissue, 6.0 gms, aggregating up to 3.4 x 3.1 x 1.4 cm. There are five lymph nodes identified, largest up to 2.5 x 1.0 x 0.4 cm (blue). Submitted in toto in two cassettes, with five lymph nodes (largest inked blue) in B1 and rest of specimen in B2.
- C. Received in formalin labeled "3 rt pelvic lymph nodes" are multiple fragments of soft tan to yellow tissue, 27.0 gms, aggregating up to 7.0 x 5.9 x 3.0 cm. There are 18 lymph nodes, identified, largest up to 3.9 x 1.4 x 0.4 cm (blue). Submitted in toto in seven cassettes as follows: 1 lymph node in C1 (largest-blue), 5 lymph nodes in C2, 5 lymph nodes in C3, 5 lymph nodes in C4, 2 lymph nodes in C5 (1 unstained, 1 green), rest of specimen is C6 and C7.
- D. Received in formalin labeled "posterior vaginal cuff bx" is a single segment of soft tan tissue, <1 gm, 2.5 x 0.5 x 0.3 cm. Submitted in toto in one cassette.
- E. Received: In formalin are three segments of soft tan tissue, unopened, unoriented
Labeled: "uterus, cervix, BSO"
Weight: 144.0 gms
Size
Uterus: 10.8 x 6.0 x 4.7 cm
Right ovary (green): 2.6 x 1.5 x 0.4 cm
Left ovary (blue): 1.7 x 1.1 x 0.5 cm
Appearance
Serosal surface: Smooth, shiny, tan, with prominent subserosal bulging
Tumor
Location: Cervix, lower uterine segment and posterior portion of uterine body
Size: 7.5 x 3.6 x 1.7 cm
Appearance: Circumferential, white, hard, fungating
Depth of invasion: >1/2 of the cervix; >1/2 of the myometrium, abutting but not involving the serosal surface
Extent: Tumor extends from the cervix to the body anterior and posterior uterine body
Invasion of contiguous structures: None identified
Distance from margins: Abutting the serosal surface, 1.1 cm from the overt paravaginal margin
Cervix: Irregular, hard as described in tumor above
Endometrium: 0.2 cm, smooth, shiny, tan with areas of hemorrhage
Myometrium: 1.4 cm in thickness, >80% grossly replaced by tumor
Right tube and ovary (green): The right tube measures 3.1 x 0.4 x 0.4 cm, is grossly unremarkable. The right ovary shows a homogeneous, tan cut surface.
Left tube and ovary (blue): The left tube measures 2.5 x 0.7 x 0.5 cm, is grossly unremarkable. The left ovary shows a homogeneous, tan cut surface.
Lymph nodes: None identified
Special studies: Pending
Other: None

KEY TO CASSETTES:

- E1-E3 - Representative of anterior cervix
E4-E6 - Representative of posterior cervix
E7 - Lower uterine segment
E7-E10 - Tumor, with cassette E7 lower uterine segment, E8 and E9 anterior uterus, E10 posterior uterus
E11 - Representative of apparent uninvolved endomyometrium
E12 - Right (green) and left (blue) adnexa
E13 - Right (green) and left (blue) parametrium

[page 3 of 3]
[REDACTED]

Surgical Pathology Report

[REDACTED]

Microscopic Description

The microscopic findings support the above diagnosis.

[REDACTED]

Source: NCI Genomic Data Commons file 79b7a692-76de-468d-8a2d-7d988e1b236c (TCGA-DR-A0ZM.14F05EE0-B739-42F8-99B0-0628ABB1B634.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).